Somatic mutation profile of tumor specimen TCGA-55-8085-01A (aliquot TCGA-55-8085-01A-11D-2238-08) from TCGA case TCGA-55-8085, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 64.6 years (23,596 days).
Specimen TCGA-55-8085-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ca4e1463-5536-460f-9dfb-5cf07edf4e56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8085-10A (Blood Derived Normal), aliquot TCGA-55-8085-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d7c5d18-2f64-4313-b8dc-e7a492269744

The open-access MAF lists 290 somatic variants for this specimen: 212 protein-altering or splice-affecting, 69 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 69, Nonsense Mutation 18, Splice Site 5, Frame Shift Del 4, RNA 4, Intron 3, 5'UTR 1, Splice Region 1, 3'Flank 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.991C>T p.Q331* | Nonsense Mutation (SNP) | VAF 18/66 reads (27%) | hotspot (GDC flag); catalogued as CM1511153, COSV52664188; called by muse, mutect2, varscan2
- ADAM22 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 44/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99717644; called by muse, mutect2, varscan2
- ADPRH | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100813342; called by muse, mutect2, varscan2
- AFF2 | c.3581C>T p.S1194L | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99665242; called by muse, mutect2, varscan2
- AL645922.1 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 41/195 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.975); catalogued as rs759293549, COSV54961597; called by muse, varscan2
- ALG11 | c.1258G>T p.G420W | Missense Mutation (SNP) | VAF 46/202 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101584368; called by muse, mutect2, varscan2
- ANAPC2 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.76); catalogued as COSV100119178; called by muse, mutect2, varscan2
- APOB | c.12011C>A p.P4004Q | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV51943225; called by muse, mutect2, varscan2
- ARHGAP31 | c.3443C>G p.S1148C | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51794734; called by muse, mutect2, varscan2
- ARL14 | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100296524; called by muse, mutect2, varscan2
- ATP6V1D | c.234C>G p.D78E | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.119); catalogued as COSV99370892; called by muse, mutect2, varscan2
- ATP8B4 | c.2974C>T p.Q992* | Nonsense Mutation (SNP) | VAF 15/79 reads (19%) | catalogued as rs754430415, COSV99466664; called by muse, mutect2, varscan2
- ATRIP | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV100202893; called by muse, mutect2, varscan2
- CACNA2D4 | c.1902T>A p.N634K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV99766093; called by muse, mutect2, varscan2
- CADM2 | c.1082G>T p.G361V (on ENST00000407528 / NM_001167674.2; = p.G363V on NM_153184.4) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV101057857; called by muse, mutect2, varscan2
- CALHM1 | c.124T>A p.C42S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100324361; called by muse, mutect2, varscan2
- CARF | c.1075G>T p.V359L | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.02); catalogued as rs749820336, COSV100247759, COSV57546062; called by muse, mutect2, varscan2
- CASD1 | c.1818A>T p.V606= | Splice Region (SNP) | VAF 6/57 reads (11%) | catalogued as COSV99802843; called by muse, mutect2
- CCDC74B | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 53/234 reads (23%) | catalogued as COSV100134597; called by muse, mutect2, varscan2
- CCSER2 | c.494C>T p.S165L | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs200068948, COSV56512306; called by muse, mutect2, varscan2
- CD1C | c.424C>A p.L142M | Missense Mutation (SNP) | VAF 95/208 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.522); catalogued as COSV100939419; called by muse, mutect2, varscan2
- CD1D | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100939629; called by muse, mutect2, varscan2
- CDH2 | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV99297675; called by muse, mutect2, varscan2
- CDK5R1 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 33/144 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.404); catalogued as COSV99912559; called by muse, mutect2, varscan2
- CELSR3 | c.6218C>G p.S2073C | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV99374321; called by muse, mutect2, varscan2
- CELSR3 | c.2951C>G p.S984* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99374324; called by muse, mutect2, varscan2
- CELSR3 | c.2648C>G p.S883C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV99374326; called by muse, mutect2, varscan2
- CEMIP2 | c.172G>T p.A58S | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV100987447; called by muse, mutect2, varscan2
- CEP350 | c.5071G>C p.E1691Q | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100854983; called by muse, mutect2, varscan2
- CEP89 | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99993760; called by muse, mutect2, varscan2
- COG1 | c.100G>T p.E34* | Nonsense Mutation (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100245407; called by muse, mutect2, varscan2
- COG5 | c.1329G>C p.L443F | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV51759452; called by muse, mutect2, varscan2
- COL4A2 | c.538del p.D180Tfs*66 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | catalogued as COSV100847183; called by mutect2, pindel, varscan2
- CPB1 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 39/209 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51577419; called by muse, mutect2, varscan2
- CRB1 | c.589A>G p.N197D | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100959146; called by muse, mutect2, varscan2
- CTNNA2 | c.1846G>T p.V616L | Missense Mutation (SNP) | VAF 48/186 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.412); catalogued as COSV58170011, COSV58189947; called by muse, mutect2, varscan2
- CTRL | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99344832; called by muse, mutect2, varscan2
- CUL3 | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100024512; called by muse, mutect2, varscan2
- CYP2R1 | c.764A>T p.D255V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV100584962; called by muse, mutect2, varscan2
- DCAF12L1 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.039); catalogued as COSV100948381, COSV100948441; called by muse, mutect2, varscan2
- DHX29 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52419783; called by muse, mutect2, varscan2
- DLG1 | c.2338G>A p.E780K (on ENST00000419354 / NM_001290983.1; = p.E802K on NM_004087.2) | Missense Mutation (SNP) | VAF 88/224 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100015683; called by muse, mutect2, varscan2
- DMBT1 | c.5516C>T p.S1839L (on ENST00000338354 / NM_001377530.1; = p.S1082L on NM_004406.3) | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs770996669, COSV100353615; called by muse, mutect2, varscan2
- DMPK | c.1149G>C p.E383D | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV99353463; called by muse, mutect2, varscan2
- DNAH14 | c.649C>G p.P217A (on ENST00000445597; = p.P40A on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100835943, COSV64782729; called by muse, mutect2, varscan2
- DNAH9 | c.4396G>A p.E1466K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99306938; called by muse, mutect2, varscan2
- DSG3 | c.2009G>T p.G670V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV57128501, COSV99934489; called by muse, mutect2, varscan2
- EMSY | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.287); catalogued as COSV100595800, COSV100595856, COSV100596116; called by muse, varscan2
- EMSY | c.2152G>A p.D718N | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.212); catalogued as COSV100595859; called by muse, varscan2
- EPB41L1 | c.1008C>G p.I336M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99151263; called by muse, mutect2, varscan2
- EPHB1 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1473516106, COSV101213645; called by muse, mutect2, varscan2
- EPHX3 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 24/63 reads (38%) | catalogued as COSV99691569; called by muse, varscan2
- ERBB3 | c.509G>C p.R170P | Missense Mutation (SNP) | VAF 49/289 reads (17%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99917434; called by muse, mutect2, varscan2
- ESRRG | c.82G>A p.D28N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.086); catalogued as COSV63184201; called by muse, mutect2, varscan2
- EVX1 | c.996C>A p.Y332* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV99764015; called by muse, mutect2
- FAM83G | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as COSV58756629, COSV58759158; called by muse, mutect2
- FBLN5 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs772620656, COSV50903020; called by muse, mutect2, varscan2
- FBXL7 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100310334; called by muse, mutect2, varscan2
- FBXO3 | c.1391G>T p.R464I | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV99682271; called by muse, mutect2, varscan2
- FGD1 | c.1029C>G p.D343E | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV64307974, COSV64308457; called by muse, mutect2, varscan2
- FGF23 | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99426583; called by muse, mutect2, varscan2
- FHDC1 | c.3013G>A p.A1005T | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1461945295, COSV99471513; called by muse, mutect2, varscan2
- FKBP9 | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV99640138; called by muse, mutect2, varscan2
- FLG | c.4834G>C p.E1612Q | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.068); catalogued as rs1179521630, COSV100911857; called by muse, mutect2, varscan2
- FMN2 | c.2377C>T p.R793* | Nonsense Mutation (SNP) | VAF 22/136 reads (16%) | catalogued as rs780928554, COSV60425069; called by muse, mutect2, varscan2
- FRMPD2 | c.3463G>A p.A1155T | Missense Mutation (SNP) | VAF 69/117 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV100564013; called by muse, mutect2, varscan2
- GIT2 | c.971C>T p.S324L (on ENST00000355312 / NM_057169.5; = p.S326L on NM_014776.5) | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100188926, COSV100189158; called by muse, mutect2, varscan2
- GLE1 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.65); catalogued as rs1469720640, COSV100012700; called by muse, mutect2, varscan2
- GLMP | c.608C>T p.P203L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.675); catalogued as COSV99828020; called by muse, mutect2, varscan2
- GPR107 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100714714; called by muse, mutect2, varscan2
- GPR176 | c.1210G>T p.E404* | Nonsense Mutation (SNP) | VAF 72/313 reads (23%) | catalogued as COSV100137346; called by muse, mutect2, varscan2
- GPR176 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV100137349; called by muse, mutect2, varscan2
- GPR61 | c.281T>A p.M94K | Missense Mutation (SNP) | VAF 68/302 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101344412; called by muse, mutect2, varscan2
- HEATR3 | c.1986G>A p.M662I | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs780894041, COSV53530951, COSV99590035; called by muse, mutect2, varscan2
- HFM1 | c.877C>G p.L293V | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV99646368; called by muse, mutect2, varscan2
- HHIPL2 | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100596989; called by muse, mutect2, varscan2
- HIVEP3 | c.1439A>T p.E480V | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99913351; called by muse, mutect2, varscan2
- HK3 | c.1906G>T p.G636C | Missense Mutation (SNP) | VAF 43/222 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99458967; called by muse, mutect2, varscan2
- IKBKB | c.1613T>C p.M538T | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV100645774; called by muse, mutect2, varscan2
- IL5RA | c.672C>G p.I224M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99843145; called by muse, mutect2, varscan2
- ITGA8 | c.2516T>A p.I839N | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV100959495, COSV65226157; called by muse, mutect2, varscan2
- ITSN2 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100743899; called by muse, mutect2, varscan2
- ITSN2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV100743904; called by muse, mutect2, varscan2
- JAG1 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as CD993785, COSV99653224; called by muse, mutect2, varscan2
- JAKMIP2 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99508828; called by muse, mutect2, varscan2
- JRKL | c.1165C>T p.L389F | Missense Mutation (SNP) | VAF 72/185 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV53594998, COSV99567444; called by muse, mutect2, varscan2
- KCNC2 | c.359C>A p.T120N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV100129428; called by muse, mutect2
- KCNN1 | c.517G>A p.G173R | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV99716168; called by muse, mutect2, varscan2
- KDM7A | c.2692G>T p.A898S | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.732); catalogued as COSV99134821; called by muse, varscan2
- KEAP1 | c.1286G>T p.G429V | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99407483, COSV99408045; called by muse, mutect2, varscan2
- KHDRBS1 | c.974G>A p.R325K | Missense Mutation (SNP) | VAF 44/229 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV100306252; called by muse, mutect2, varscan2
- KHSRP | c.1435G>C p.G479R | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101231216; called by muse, mutect2, varscan2
- KIF17 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.211); catalogued as COSV99929444; called by muse, mutect2, varscan2
- KPNA2 | c.47G>A p.R16K | Missense Mutation (SNP) | VAF 89/314 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100388833; called by muse, mutect2, varscan2
- KRT10 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 69/217 reads (32%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as COSV54089351, COSV99510183; called by muse, mutect2, varscan2
- LDB2 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100453449, COSV100454251; called by muse, mutect2, varscan2
- LMX1A | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 85/184 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99672814; called by muse, mutect2, varscan2
- LONRF2 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.029); catalogued as COSV101111009; called by muse, mutect2, varscan2
- LRCH2 | c.1880G>T p.G627V | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as COSV100407208; called by muse, mutect2, varscan2
- LRCH2 | c.1879G>T p.G627W | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100407213, COSV57745026; called by muse, mutect2, varscan2
- LRP2 | c.11281G>A p.E3761K | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55548323; called by muse, mutect2, varscan2
- MAP1B | c.792T>G p.I264M | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99702702; called by muse, varscan2
- MATK | c.488G>T p.G163V (on ENST00000310132 / NM_139355.3; = p.G164V on NM_002378.4) | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.825); catalogued as COSV100036187; called by muse, mutect2, varscan2
- MED23 | c.853A>C p.N285H | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.844); catalogued as rs756429077, COSV100645255; called by muse, mutect2, varscan2
- MEIS1 | c.659C>T p.T220M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs376358636; called by muse, mutect2, varscan2
- MMP10 | c.574G>A p.G192R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54245739; called by muse, mutect2, varscan2
- MRGBP | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100978293; called by muse, mutect2, varscan2
- MTHFR | c.1966C>T p.P656S | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100453741; called by muse, varscan2
- MTR | c.3660C>G p.F1220L | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100855457; called by muse, mutect2, varscan2
- MXRA5 | c.1312G>C p.D438H | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV99476849, COSV99478185; called by muse, mutect2, varscan2
- MYO7B | c.395C>A p.P132Q | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101267784, COSV67348641; called by muse, mutect2
- MYOF | c.4202G>T p.R1401L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.927); catalogued as rs572212231, COSV100825981; called by muse, mutect2, varscan2
- NCEH1 | c.1163A>T p.D388V (on ENST00000538775; = p.D348V on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99860273; called by muse, mutect2, varscan2
- NEK10 | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 43/174 reads (25%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99835433; called by muse, mutect2, varscan2
- NEU4 | c.821G>A p.W274* (on ENST00000391969 / NM_001167602.3; = p.W286* on NM_080741.4) | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as COSV100372144; called by muse, mutect2, varscan2
- NLGN4X | c.1281G>T p.W427C | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99322970; called by muse, mutect2, varscan2
- NOL4 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99307637; called by muse, mutect2, varscan2
- NOL4 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.569); catalogued as COSV99307638; called by muse, mutect2, varscan2
- NR4A3 | c.1726C>A p.L576M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.715); catalogued as COSV100432593; called by muse, mutect2, varscan2
- NRG1 | c.235T>C p.S79P (on ENST00000523534; = p.S226P on NM_013962.2) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV73057926; called by muse, mutect2, varscan2
- NRXN3 | c.1855C>T p.R619C (on ENST00000335750 / NM_001330195.2; = p.R246C on NM_004796.6) | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764624479, COSV59714381; called by muse, mutect2, varscan2
- NRXN3 | c.2611G>T p.D871Y (on ENST00000335750 / NM_001330195.2; = p.D498Y on NM_004796.6) | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100206382; called by muse, mutect2, varscan2
- NTNG1 | c.1285C>T p.H429Y | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV64271797; called by muse, mutect2, varscan2
- OGDH | c.708G>C p.Q236H | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV99759289; called by muse, mutect2, varscan2
- OR10K1 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56871180, COSV99193795; called by muse, mutect2, varscan2
- OR1L8 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV100508613; called by muse, mutect2, varscan2
- PARD3 | c.341C>T p.S114L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV100401530; called by muse, mutect2, varscan2
- PDGFRA | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as rs1189746481, COSV57268221; called by muse, mutect2, varscan2
- PDYN | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138498390, COSV54101109; called by muse, mutect2, varscan2
- PLCL1 | c.3145A>T p.I1049L | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV70880201; called by muse, mutect2, varscan2
- PLEC | c.1192G>A p.A398T (on ENST00000322810 / NM_201380.4; = p.A288T on NM_000445.5) | Missense Mutation (SNP) | VAF 67/329 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs782693579, COSV59613072; called by muse, mutect2, varscan2
- PLXNA2 | c.2976G>C p.Q992H | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.885); catalogued as COSV100885657; called by muse, mutect2, varscan2
- PNLIP | c.863C>A p.T288N | Missense Mutation (SNP) | VAF 54/172 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.344); catalogued as COSV100981896; called by muse, mutect2, varscan2
- POGLUT1 | c.1070G>A p.C357Y | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as rs1192170907, COSV99809727; called by muse, mutect2, varscan2
- PPP3CA | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100547878, COSV100548159; called by muse, mutect2, varscan2
- PRDM2 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 58/195 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as COSV99342250; called by muse, mutect2, varscan2
- PRDM2 | c.1459T>G p.Y487D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99342252; called by muse, mutect2, varscan2
- PRRC2B | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 59/216 reads (27%) | catalogued as COSV100622001, COSV100622111; called by muse, mutect2, varscan2
- PRRX1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53411616, COSV53419369; called by muse, mutect2, varscan2
- PRSS55 | c.244C>A p.Q82K | Missense Mutation (SNP) | VAF 117/377 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV100153844; called by muse, mutect2, varscan2
- PSG8 | c.767A>T p.D256V | Missense Mutation (SNP) | VAF 88/243 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs757563975, COSV100126471; called by muse, mutect2, varscan2
- PTPRO | c.963C>G p.Y321* | Nonsense Mutation (SNP) | VAF 17/55 reads (31%) | catalogued as COSV55521963, COSV99841205; called by muse, mutect2, varscan2
- RAB24 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100293672; called by muse, mutect2, varscan2
- RERE | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 27/157 reads (17%) | catalogued as COSV100556983; called by muse, mutect2, varscan2
- RIPK1 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as COSV99453958, COSV99454661; called by muse, mutect2, varscan2
- RNASE2 | c.67G>T p.G23C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.75); catalogued as COSV58941189; called by muse, mutect2, varscan2
- RNF125 | c.613-2A>T p.X205_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV54186727, COSV99470580; called by muse, mutect2, varscan2
- RNF125 | c.613-1G>T p.X205_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99470581; called by muse, mutect2, varscan2
- RPE65 | c.11+1G>T p.X4_splice | Splice Site (SNP) | VAF 19/58 reads (33%) | catalogued as CS120085, COSV99254149; called by muse, mutect2, varscan2
- RPS6KA5 | c.629C>T p.A210V | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV100002902; called by muse, mutect2
- RRP1B | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV61478363; called by muse, mutect2, varscan2
- RTTN | c.3607G>C p.V1203L | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV99733197; called by muse, mutect2, varscan2
- SASH1 | c.3022A>C p.S1008R | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as rs746126688, COSV100821320; called by muse, mutect2, varscan2
- SEMA3C | c.223C>G p.L75V | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as COSV54858349, COSV99543427; called by muse, mutect2, varscan2
- SERPINB2 | c.1192A>G p.I398V | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV99449491; called by muse, mutect2, varscan2
- SETD6 | c.471G>A p.M157I (on ENST00000219315 / NM_001160305.4; = p.M133I on NM_024860.3) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.934); catalogued as rs1307357131, COSV99262369; called by muse, mutect2, varscan2
- SETX | c.3091G>C p.E1031Q | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99810363; called by muse, mutect2, varscan2
- SGMS1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 26/149 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); catalogued as COSV100693568; called by muse, mutect2, varscan2
- SLC16A3 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV101125910; called by muse, mutect2, varscan2
- SLC25A47 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs373202957; called by muse, mutect2, varscan2
- SLC26A3 | c.2245G>A p.G749R | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV60641186; called by muse, mutect2, varscan2
- SLIT2 | c.2690T>C p.L897S | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99885686; called by muse, mutect2, varscan2
- SMC1B | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.749); catalogued as rs776231146, COSV100663386; called by muse, mutect2, varscan2
- SPAG9 | c.2428G>C p.E810Q (on ENST00000262013 / NM_001130528.3; = p.E796Q on NM_003971.6) | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV100005572; called by muse, mutect2, varscan2
- SPATA21 | c.15C>A p.N5K | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100131188; called by muse, mutect2, varscan2
- SPTA1 | c.5433-1G>C p.X1811_splice | Splice Site (SNP) | VAF 17/80 reads (21%) | catalogued as COSV100935252; called by muse, mutect2, varscan2
- STS | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs766689052, COSV99481488; called by muse, mutect2, varscan2
- SUSD1 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV100813415; called by muse, mutect2, varscan2
- TAAR2 | c.124G>T p.V42F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV99255721; called by muse, mutect2, varscan2
- TAS2R41 | c.548C>G p.S183C | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.035); catalogued as COSV101281503; called by muse, mutect2, varscan2
- TAS2R60 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100223545, COSV100223616; called by muse, mutect2, varscan2
- TBC1D24 | c.1145T>A p.F382Y (on ENST00000646147 / NM_001199107.2; = p.F376Y on NM_020705.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV99565156; called by muse, mutect2, varscan2
- TFG | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53749805; called by muse, mutect2, varscan2
- TIGD7 | c.25A>G p.T9A | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV99239936; called by muse, mutect2, varscan2
- TMEM67 | c.1148C>G p.S383C | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60035414, COSV60039207; called by muse, mutect2, varscan2
- TONSL | c.3414G>A p.M1138I | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV101340283; called by muse, varscan2
- TRIM33 | c.972G>C p.E324D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.073); catalogued as COSV100635585, COSV61825393; called by muse, mutect2, varscan2
- TRIM8 | c.416A>T p.D139V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.36); catalogued as COSV100193328; called by muse, mutect2, varscan2
- TRPA1 | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100084724; called by muse, mutect2, varscan2
- TRPC4 | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100157395, COSV59017583; called by muse, mutect2, varscan2
- TRPM8 | c.3262A>T p.K1088* | Nonsense Mutation (SNP) | VAF 37/127 reads (29%) | catalogued as COSV100224325; called by muse, mutect2, varscan2
- TSHZ3 | c.2593C>G p.P865A | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as rs1224933200, COSV53685631, COSV99552172; called by muse, mutect2, varscan2
- TTBK1 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs748813341, COSV99445147; called by muse, mutect2, varscan2
- TTC5 | c.584C>G p.S195C | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV51870993, COSV99351912; called by muse, mutect2, varscan2
- TXNRD2 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101266158; called by muse, mutect2, varscan2
- UBAC1 | c.1189A>G p.R397G | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV100873812; called by muse, mutect2, varscan2
- UBTD1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1481751005, COSV100080982; called by muse, mutect2, varscan2
- UGT2B7 | c.1120C>A p.H374N | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100535257; called by muse, mutect2, varscan2
- UHMK1 | c.695T>G p.L232* | Nonsense Mutation (SNP) | VAF 27/149 reads (18%) | catalogued as COSV99966313; called by muse, mutect2, varscan2
- UHRF1BP1L | c.3613G>A p.D1205N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV99691904; called by muse, mutect2, varscan2
- USH1G | c.709G>T p.G237W | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100140558; called by muse, mutect2, varscan2
- WDR4 | c.976-1G>A p.X326_splice | Splice Site (SNP) | VAF 9/46 reads (20%) | catalogued as COSV100375329, COSV100375332; called by muse, mutect2, varscan2
- WNK3 | c.2062G>C p.E688Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as COSV100671792; called by muse, mutect2, varscan2
- ZBTB5 | c.1051G>C p.E351Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV100312859; called by muse, mutect2, varscan2
- ZDHHC19 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV99579735; called by muse, mutect2, varscan2
- ZFC3H1 | c.4760G>T p.C1587F | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101110624; called by muse, mutect2, varscan2
- ZFHX4 | c.7819C>A p.R2607S | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50480018, COSV50538350, COSV99265401; called by muse, mutect2
- ZKSCAN4 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV101043526; called by muse, mutect2, varscan2
- ZNF236 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs373910373, COSV53485621, COSV99470575; called by muse, mutect2, varscan2
- ZNF276 | c.809G>T p.R270L (on ENST00000443381 / NM_001113525.2; = p.R195L on NM_152287.4) | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs147766861, COSV99235158; called by muse, mutect2, varscan2
- ZNF425 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs1424026566, COSV65200858; called by muse, mutect2, varscan2
- ZNF615 | c.1595G>A p.R532Q | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as rs781201122, COSV65032289, COSV65033860; called by muse, mutect2, varscan2
- ZNF777 | c.1519C>A p.Q507K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV99925264; called by muse, mutect2, varscan2
- ACACA | c.5584A>T p.I1862F | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- BMP10 | c.876del p.S292Rfs*11 | Frame Shift Del (DEL) | VAF 15/80 reads (19%) | called by mutect2, pindel, varscan2
- COL12A1 | c.8616del p.K2873Sfs*16 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- IGHA1 | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- IGLV2-23 | c.263C>G p.S88C | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MCM10 | c.1711del p.E571Rfs*2 (on ENST00000484800 / NM_182751.3; = p.E570Rfs*2 on NM_018518.5) | Frame Shift Del (DEL) | VAF 15/69 reads (22%) | called by mutect2, pindel, varscan2
- NEUROG3 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- WASHC2C | c.3712G>A p.D1238N (on ENST00000336378; = p.D1217N on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AIFM1 | c.441C>T p.A147= | Silent (SNP) | VAF 53/126 reads (42%) | catalogued as COSV99781259; called by muse, mutect2, varscan2
- ANKIB1 | c.2970A>T p.P990= | Silent (SNP) | VAF 31/132 reads (23%) | catalogued as COSV99729543; called by muse, mutect2, varscan2
- ANO10 | c.813G>A p.R271= | Silent (SNP) | VAF 24/89 reads (27%) | catalogued as COSV99428771; called by muse, mutect2, varscan2
- ARHGAP10 | c.1878T>C p.P626= | Silent (SNP) | VAF 42/156 reads (27%) | catalogued as COSV100331518; called by muse, mutect2, varscan2
- ARHGAP36 | c.985C>T p.L329= | Silent (SNP) | VAF 165/316 reads (52%) | catalogued as COSV99357976; called by muse, mutect2, varscan2
- ARPP19 | c.270C>T p.D90= | Silent (SNP) | VAF 30/163 reads (18%) | catalogued as COSV51119816; called by muse, mutect2, varscan2
- BCL11A | c.966G>C p.A322= (on ENST00000335712 / NM_001365609.1; = p.A356= on NM_018014.4) | Silent (SNP) | VAF 46/127 reads (36%) | catalogued as COSV100186105; called by muse, mutect2, varscan2
- BRINP1 | c.1293C>T p.G431= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs751477480, COSV56310244; called by muse, mutect2, varscan2
- BTNL9 | c.894C>T p.L298= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs762054473, COSV100576197; called by muse, mutect2, varscan2
- CACNA1H | c.4608C>T p.I1536= | Silent (SNP) | VAF 118/491 reads (24%) | catalogued as rs777641943, COSV62008012; ClinVar: likely benign; called by muse, mutect2, varscan2
- CCDC32 | c.117C>T p.F39= | Silent (SNP) | VAF 70/251 reads (28%) | catalogued as rs772591317, COSV100785983; called by muse, mutect2, varscan2
- CEMIP2 | c.171G>A p.R57= | Silent (SNP) | VAF 35/98 reads (36%) | catalogued as COSV100987448; called by muse, mutect2, varscan2
- CERS2 | c.966C>T p.L322= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV99645382; called by muse, mutect2, varscan2
- COL4A4 | c.2751C>T p.P917= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs544472944, COSV100306445, COSV100307353; called by muse, mutect2, varscan2
- CPNE5 | c.1335A>T p.A445= | Silent (SNP) | VAF 52/93 reads (56%) | catalogued as COSV99783080; called by muse, mutect2, varscan2
- ECPAS | c.3294T>A p.G1098= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99398852; called by muse, mutect2, varscan2
- ELOVL4 | c.834T>G p.A278= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as COSV100876361; called by muse, mutect2, varscan2
- EMX2 | c.681G>T p.G227= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV101463626; called by muse, mutect2, varscan2
- EPHA6 | c.2637C>A p.G879= (on ENST00000389672 / NM_001080448.3; = p.G271= on NM_173655.4) | Silent (SNP) | VAF 70/305 reads (23%) | catalogued as rs201543430, COSV101064430; called by muse, varscan2
- FAM118A | c.456G>C p.L152= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV53417595; called by muse, mutect2, varscan2
- FOLR3 | c.45G>A p.L15= | Silent (SNP) | VAF 82/351 reads (23%) | catalogued as COSV100281820; called by muse, mutect2, varscan2
- GFRAL | c.855G>T p.T285= | Silent (SNP) | VAF 126/240 reads (53%) | catalogued as rs564015610, COSV100475572; called by muse, mutect2, varscan2
- GLRA2 | c.726C>A p.T242= | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV99491405; called by muse, mutect2, varscan2
- HAVCR2 | c.45G>T p.L15= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as COSV100324869, COSV57152920; called by muse, mutect2, varscan2
- HMGB4 | c.540G>T p.G180= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV53886137, COSV99592732; called by muse, mutect2, varscan2
- HPCA | c.204C>G p.V68= | Silent (SNP) | VAF 49/159 reads (31%) | catalogued as COSV100992191; called by muse, mutect2, varscan2
- HTR3C | c.921C>A p.L307= | Silent (SNP) | VAF 122/304 reads (40%) | catalogued as COSV100570695; called by muse, mutect2, varscan2
- ITGA8 | c.2517C>T p.I839= | Silent (SNP) | VAF 30/140 reads (21%) | catalogued as COSV65229163; called by muse, mutect2, varscan2
- KCNH8 | c.96C>A p.A32= | Silent (SNP) | VAF 42/151 reads (28%) | catalogued as COSV100110546, COSV100111176; called by muse, mutect2, varscan2
- LONRF2 | c.2205C>T p.I735= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV101111007; called by muse, mutect2, varscan2
- LPA | c.1014G>T p.G338= | Silent (SNP) | VAF 18/662 reads (3%) | catalogued as COSV100305825, COSV100307494; called by muse, mutect2
- MAP1B | c.894C>A p.I298= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV57103938, COSV99702704; called by muse, varscan2
- MEI1 | c.2742C>A p.L914= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100300181; called by muse, mutect2, varscan2
- MINAR1 | c.2232C>T p.L744= | Silent (SNP) | VAF 35/116 reads (30%) | catalogued as COSV100549072; called by muse, mutect2, varscan2
- NFKBID | c.306G>A p.E102= (on ENST00000396901; = p.E254= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as COSV100756498; called by muse, mutect2, varscan2
- NID2 | c.3342G>A p.Q1114= | Silent (SNP) | VAF 26/174 reads (15%) | catalogued as COSV99356945; called by muse, mutect2, varscan2
- NLRP1 | c.2469T>C p.S823= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV99334937; called by muse, mutect2, varscan2
- NSD1 | c.573C>T p.A191= | Silent (SNP) | VAF 42/173 reads (24%) | catalogued as COSV100729629; called by muse, mutect2, varscan2
- OR2T33 | c.459C>T p.D153= | Silent (SNP) | VAF 79/195 reads (41%) | catalogued as rs764565834, COSV58817401, COSV58817854; called by muse, mutect2, varscan2
- OR5D16 | c.138G>T p.G46= | Silent (SNP) | VAF 62/230 reads (27%) | catalogued as COSV101004069; called by muse, mutect2, varscan2
- OR8J3 | c.381T>C p.C127= | Silent (SNP) | VAF 52/157 reads (33%) | catalogued as rs189377785, COSV100040943; called by muse, mutect2, varscan2
- OSBPL3 | c.1332C>T p.I444= | Silent (SNP) | VAF 41/217 reads (19%) | catalogued as rs368806105; called by muse, mutect2, varscan2
- P4HB | c.573C>T p.D191= | Silent (SNP) | VAF 103/361 reads (29%) | catalogued as rs141223466; called by muse, mutect2, varscan2
- PCDHB13 | c.975T>A p.A325= | Silent (SNP) | VAF 64/220 reads (29%) | catalogued as COSV99507561; called by muse, mutect2, varscan2
- PCLO | c.3747C>T p.L1249= | Silent (SNP) | VAF 37/160 reads (23%) | catalogued as COSV100434871; called by muse, mutect2, varscan2
- PFKFB2 | c.1408C>T p.L470= | Silent (SNP) | VAF 58/349 reads (17%) | catalogued as rs149056956; called by muse, mutect2, varscan2
- PI4KA | c.1881G>A p.L627= | Silent (SNP) | VAF 25/66 reads (38%) | catalogued as rs763961715, COSV55420399, COSV99747467; called by muse, mutect2, varscan2
- PLEKHO1 | c.1137G>C p.L379= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV50309893; called by muse, mutect2, varscan2
- POF1B | c.1494C>T p.D498= | Silent (SNP) | VAF 29/47 reads (62%) | catalogued as COSV99426563; called by muse, mutect2, varscan2
- PSMD10 | c.456G>A p.L152= | Silent (SNP) | VAF 57/115 reads (50%) | catalogued as COSV99480718; called by muse, mutect2, varscan2
- QSOX2 | c.225C>T p.T75= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs782555742, COSV100699818; called by muse, mutect2, varscan2
- RESF1 | c.4377G>A p.L1459= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as COSV100440476, COSV57024928; called by muse, mutect2, varscan2
- S100A8 | c.165C>T p.F55= | Silent (SNP) | VAF 37/230 reads (16%) | catalogued as COSV100907108; called by muse, mutect2, varscan2
- SAP30 | c.246C>T p.N82= | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as rs1404703758, COSV99633113; called by muse, mutect2, varscan2
- SLC5A7 | c.678G>A p.K226= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV99887025; called by muse, mutect2, varscan2
- SPAM1 | c.600G>T p.L200= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV99773227; called by muse, mutect2, varscan2
- TADA2A | c.1260C>T p.I420= | Silent (SNP) | VAF 85/333 reads (26%) | called by muse, mutect2, varscan2
- TAS2R60 | c.556C>A p.R186= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as COSV60332390; called by muse, mutect2
- TEX14 | c.2178C>A p.S726= (on ENST00000240361 / NM_001201457.2; = p.S720= on NM_031272.5) | Silent (SNP) | VAF 105/409 reads (26%) | catalogued as COSV99542899; called by muse, mutect2, varscan2
- THUMPD1 | c.924G>A p.Q308= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV101189721; called by muse, mutect2, varscan2
- TNIP1 | c.1047G>A p.V349= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100161599; called by muse, mutect2, varscan2
- TRAV9-1 | c.120G>T p.V40= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- TRIM56 | c.2229G>T p.G743= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs766393585, COSV100047525; called by muse, mutect2, varscan2
- UCHL1 | c.546G>A p.P182= | Silent (SNP) | VAF 49/229 reads (21%) | catalogued as COSV52653413; called by muse, mutect2, varscan2
- UNC79 | c.1575G>T p.R525= (on ENST00000393151 / NM_001346218.2; = p.R348= on NM_020818.5) | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99828934; called by muse, mutect2, varscan2
- ZFHX4 | c.3045C>T p.R1015= | Silent (SNP) | VAF 122/259 reads (47%) | catalogued as COSV99265398; called by muse, mutect2, varscan2
- ZNF678 | c.582A>T p.S194= | Silent (SNP) | VAF 35/285 reads (12%) | catalogued as COSV100652882; called by muse, mutect2, varscan2
- ZSWIM8 | c.1644G>A p.K548= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs778507282, COSV101290061; called by muse, mutect2, varscan2
- ZSWIM8 | c.2469G>A p.T823= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as rs768043858, COSV67131498; called by muse, mutect2, varscan2
- AC073310.1 | n.606A>T | RNA (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- ADRA1A | chr8:26766112 C>T | 3'Flank (SNP) | VAF 41/198 reads (21%) | catalogued as COSV52375742; called by muse, mutect2, varscan2
- C11orf40 | n.190G>A | RNA (SNP) | VAF 14/72 reads (19%) | catalogued as rs769106575, COSV56892244; called by muse, mutect2, varscan2
- CFLAR | c.523+248C>T | Intron (SNP) | VAF 25/118 reads (21%) | catalogued as COSV100009658; called by muse, mutect2, varscan2
- KCNAB1 | c.275+22404C>T | Intron (SNP) | VAF 25/81 reads (31%) | catalogued as COSV101051355; called by muse, mutect2, varscan2
- PTX4 | c.142-390C>A | Intron (SNP) | VAF 37/117 reads (32%) | catalogued as COSV99560634; called by muse, mutect2, varscan2
- SLC22A17 | n.1342G>T | RNA (SNP) | VAF 79/212 reads (37%) | catalogued as COSV99248953; called by muse, mutect2, varscan2
- SNORD115-20 | n.23A>T | RNA (SNP) | VAF 156/569 reads (27%) | called by muse, mutect2, varscan2
- TREML2 | c.-79G>T | 5'UTR (SNP) | VAF 14/92 reads (15%) | catalogued as COSV101530184; called by muse, varscan2
